Somatic mutation profile of tumor specimen TCGA-FD-A3B4-01A (aliquot TCGA-FD-A3B4-01A-12D-A202-08) from TCGA case TCGA-FD-A3B4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 55.8 years (20,379 days).
Specimen TCGA-FD-A3B4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eded83bd-fa14-4ec7-a38d-1d8e76cae947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B4-10A (Blood Derived Normal), aliquot TCGA-FD-A3B4-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd0bc38e-48b6-48c8-9fb7-3a0a79dad7cb

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL3 | c.1202T>G p.V401G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV60199108; called by muse, mutect2, varscan2
- ABCB1 | c.2413G>T p.D805Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55951709, COSV55958888; called by muse, mutect2, varscan2
- ABCC9 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV53971853; called by muse, mutect2, varscan2
- ANO10 | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99428666; called by muse, mutect2, varscan2
- ATP10B | c.2980G>C p.A994P | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.272); catalogued as COSV59152033; called by muse, mutect2, varscan2
- BBS12 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV58562096; called by muse, mutect2, varscan2
- BPIFA3 | c.276C>A p.S92R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.221); catalogued as COSV64925868; called by muse, mutect2, varscan2
- BRWD3 | c.2143G>T p.A715S | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV64748292; called by muse, mutect2, varscan2
- CHST7 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs766923926, COSV52099992, COSV52101315; called by muse, mutect2, varscan2
- DCAF12L2 | c.244A>T p.R82W | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV63581737; called by muse, mutect2, varscan2
- ELP2 | c.1467A>T p.Q489H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV60851117; called by muse, varscan2
- ERAS | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV54432831; called by muse, mutect2, varscan2
- ERC2 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55622886; called by muse, mutect2, varscan2
- EXOC1 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs373611067, COSV100637863; called by muse, mutect2, varscan2
- F8 | c.4171G>T p.D1391Y | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV64273586; called by muse, mutect2, varscan2
- FAN1 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV62950646; called by muse, mutect2, varscan2
- FAT1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71673967; called by muse, mutect2, varscan2
- FGB | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs755819016, COSV57418349; called by muse, mutect2, varscan2
- FLG | c.3791G>A p.R1264K | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.131); catalogued as rs902207448, COSV64241958; called by muse, mutect2, varscan2
- GLOD5 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57489270; called by muse, mutect2, varscan2
- GNG3 | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV53655061; called by muse, mutect2, varscan2
- HECW1 | c.3763C>A p.R1255S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV67825458, COSV67829709; called by muse, mutect2, varscan2
- HMGCS2 | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65567910; called by muse, mutect2, varscan2
- HYDIN | c.5599C>A p.Q1867K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV99993145; called by muse, mutect2, varscan2
- IFNLR1 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 76/220 reads (35%) | catalogued as COSV59525928; called by muse, mutect2, varscan2
- KCNG2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs1301158656, COSV60267891; called by muse, mutect2, varscan2
- KCNH7 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV59797022; called by muse, mutect2, varscan2
- KIF25 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63027375; called by muse, mutect2, varscan2
- MTR | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV63968030; called by muse, mutect2, varscan2
- NHS | c.2186G>T p.C729F | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66275092; called by muse, mutect2, varscan2
- OR10C1 | c.350C>A p.A117E (on ENST00000622521; = p.A115E on NM_013941.3) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV65822870; called by muse, mutect2, varscan2
- OR2A2 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs373747609; called by muse, mutect2, varscan2
- OR5M10 | c.768C>A p.F256L | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.35); catalogued as COSV73242322; called by muse, mutect2, varscan2
- OR5T1 | c.589C>A p.L197I | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV57302730; called by muse, mutect2, varscan2
- PACS2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1379927163, COSV57652732; called by muse, mutect2, varscan2
- PCDHGA8 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs373432896; called by muse, mutect2, varscan2
- PGAP6 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376351004, COSV51739322; called by mutect2, varscan2
- PHLDA1 | c.751del p.Y251Tfs*5 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV56997397; called by mutect2, pindel, varscan2
- PON2 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV56001964; called by muse, mutect2, varscan2
- POSTN | c.493T>A p.L165I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65712976; called by muse, mutect2, varscan2
- PTPRG | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs749642322, COSV55641785; called by muse, mutect2, varscan2
- RAE1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV64798213; called by muse, mutect2, varscan2
- RHOXF1 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.588); catalogued as COSV54294621; called by muse, mutect2, varscan2
- RNFT2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746690644, COSV99985360; called by muse, mutect2, varscan2
- RP1L1 | c.1468G>T p.G490W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV66755109; called by muse, mutect2, varscan2
- RTTN | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55345022; called by muse, mutect2, varscan2
- SLC8A1 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60480922; called by muse, mutect2, varscan2
- SYCP2L | c.2160T>A p.Y720* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs1350459618, COSV99305384; called by muse, mutect2, varscan2
- TMEM151A | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV100516933, COSV100516991; called by muse, mutect2, varscan2
- TRIM71 | c.1622G>C p.S541T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV67470991; called by muse, mutect2, varscan2
- TTC7B | c.2219C>A p.A740D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV60631374; called by muse, mutect2, varscan2
- TTN | c.77272G>T p.G25758C (on ENST00000591111; = p.G18334C on NM_003319.4) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV60067733; called by muse, mutect2, varscan2
- UNC13C | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.261); catalogued as COSV52873867; called by muse, mutect2, varscan2
- USH2A | c.3715G>T p.A1239S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV56370642; called by muse, mutect2, varscan2
- USP32 | c.3937G>A p.V1313I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV56269032; called by muse, mutect2, varscan2
- VCAN | c.3989G>T p.R1330I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV54105298; called by muse, mutect2, varscan2
- ZBTB33 | c.58A>T p.N20Y | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV58533990; called by muse, mutect2, varscan2
- ZBTB45 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99564454; called by muse, mutect2, varscan2
- ZNF804A | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100167933, COSV100168596; called by muse, mutect2, varscan2
- RUFY1 | c.700_701del p.L234Kfs*5 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SULT1C4 | c.203_204dup p.Q69Yfs*24 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- ZNF492 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- BATF | c.300G>T p.T100= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV54375881, COSV54376012; called by muse, mutect2, varscan2
- CFAP61 | c.436C>T p.L146= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV55629786, COSV99842414; called by muse, mutect2, varscan2
- CHD5 | c.4635G>A p.S1545= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs140639533; called by muse, mutect2, varscan2
- CLGN | c.39G>T p.L13= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100346537, COSV57774718; called by muse, mutect2, varscan2
- COMP | c.1296C>T p.S432= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55874816; called by muse, mutect2, varscan2
- DBX2 | c.528A>C p.T176= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV60337730; called by muse, mutect2, varscan2
- GKN1 | c.525C>T p.D175= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV65006523; called by muse, mutect2, varscan2
- MAG | c.1026G>A p.T342= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs200660504, COSV62700616; called by muse, mutect2, varscan2
- MAGEA12 | c.726C>A p.P242= | Silent (SNP) | VAF 53/254 reads (21%) | catalogued as COSV63294827; called by muse, mutect2, varscan2
- NME8 | c.978C>G p.L326= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs759874838, COSV52250360, COSV52254705; called by muse, mutect2, varscan2
- PCDHGA3 | c.2295G>A p.K765= | Silent (SNP) | VAF 31/155 reads (20%) | catalogued as rs775563489, COSV53949467; called by muse, mutect2, varscan2
- PLEKHG4 | c.204G>A p.R68= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV64612766; called by muse, mutect2, varscan2
- PRSS35 | c.135C>T p.L45= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs1381074158, COSV63800580; called by muse, mutect2, varscan2
- PTPRT | c.147C>A p.T49= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs190021886, COSV61969080, COSV61981784; called by muse, mutect2, varscan2
- SMYD2 | c.354C>A p.I118= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as COSV65290909, COSV65291909; called by muse, mutect2, varscan2
- TCOF1 | c.3345C>A p.T1115= (on ENST00000377797 / NM_001135243.1; = p.T1038= on NM_000356.4) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV60348504; called by muse, mutect2, varscan2
- USP54 | c.4734C>T p.G1578= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV60442608; called by muse, mutect2, varscan2
- XIRP2 | c.*173C>A | 3'UTR (SNP) | VAF 24/66 reads (36%) | catalogued as rs762357613, COSV54700995; called by muse, mutect2, varscan2
